TCGA case TCGA-32-2494 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital (AZ). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c50998f6-369c-48fe-a8e7-a4c5a4cef0e6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 632 days (1.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 58.0 years (21,198 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 62 days; Treatment dose: 75 mg/m2; Prescribed dose: 140; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 62 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Radioisotope; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 62 days; Number of fractions: 30.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 90 days; Days to treatment end: 94 days; Number of cycles: 1; Treatment dose: 150 mg/m2; Prescribed dose: 270; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 120 days; Days to treatment end: 403 days (1.1 years); Number of cycles: 11; Treatment dose: 200 mg/m2; Prescribed dose: 360; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 488 days (1.3 years); Days to treatment end: 550 days (1.5 years); Prescribed dose: 600; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 488 days (1.3 years); Days to treatment end: 550 days (1.5 years); Number of cycles: 4; Prescribed dose: 160; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 501 days (1.4 years); Days to treatment end: 518 days (1.4 years); Treatment dose: 3,900 cGy; Number of fractions: 12; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 620 days (1.7 years); Days to treatment end: 620 days (1.7 years); Treatment dose: 10 mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 620 days (1.7 years); Days to treatment end: 632 days (1.7 years); Number of cycles: 1; Prescribed dose: 140; Prescribed dose units: mg/day; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 59.4 years (21,686 days); Days to diagnosis: 488 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (2 entries)
- Day 488 (post initial treatment): Progression or recurrence: Yes; Days to progression: 488 days (1.3 years).
- Days to follow up: 632 days (1.7 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-32-2494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-32-2494-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 10; Percent stromal cells: 5.
  Slide TCGA-32-2494-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-32-2494-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 5: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 6, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 632 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 632 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 488 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-32-2494-01A-01D-1224-01): tumor purity 0.58, ploidy 1.94, whole-genome doublings 0.
